Surgical pathology report (de-identified scan), TCGA case TCGA-5U-AB0E, project TCGA-THYM (Thymoma), tissue source site Regina Elena National Cancer Institute, specimen TCGA-5U-AB0E-01A (Primary Tumor).

ICD O-3
Thymoma, type B3 malignant
8585/3
Site: Anterior mediastinum
(38.1)
gn 1/29/14

SURNAME and NAME :

Sex: M

BIRTH DATE:

Hospital:

Department: Thoracic Surgery

Clinical informations: Since
32x14 mm.

symptoms of Myasthenia gravis. Anterior mediastinal mass

Type of specimen: radical Thymectomy

Material sent: A) neoplasia + cardio-phrenic left adipous tissue; B) thymic right horn + right cardio-phrenic adipous tissue.

Macroscopical description: A) neoplasia + cardio-phrenic left adipous tissue: in the adipous tissue a well circumscribed mass measuring 3x3x1 was found. Near to the main mass a smaller nodule was found (blocks 1-4 neoplasia, block 5 distinct nodule, block 6 adipous tissue, blocks 7-9 sampling of adipous tissue, block 10 adipous tissue from the cardio-phrenic left adipous tissue);

B) thymic right horn + right cardio-phrenic adipous tissue: predominantly adipous tissue of 19x6x1.5 cm, blocks 11-13.

Microscopical description: A) B3 type thymoma according to the WHO 2004 classification. The neoplasia is partially encapsulated and it infiltrates focally through the capsule, by invading the mediastinal fat tissue. The distinct nodule is an other small (cm 1.5) B3 thymoma, partially encapsulated. Moreover in the far mediastinal tissue an additional small thymoma nodule was found. In the adipous tissue of cardio-phrenic left corner 4 reactive lymph nodes were found.

Immunohistochemical stainings showed positivity of Epithelial cells for Cytokeratins MNF116 and negativity for CD117. Cortical type thymocytes Tdt+ were the predominant lymphocytes. Rare B type lymphocytes, mainly in thymic remnants, were found.

B) thymic right horn + right cardio-phrenic adipous tissue: adipous tissue with thymic remnants without particular alterations.

Diagnosis: B3 thymoma with multiple distinct nodules: the biggest nodule infiltrates the mediastinal tissue adjacent to the mass; the synchronous minor neoplastic nodules are incompletely encapsulated but no invasive tendency was found (St. IIA according to Masaoka-Koga).

Acceptance date:

Reporting date:

Pathologist

Source: NCI Genomic Data Commons file 877ecdfa-0615-40fb-8508-eb62fef9bba8 (TCGA-5U-AB0E.FB1E07B4-3B1C-447C-BEBE-72225EB792DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).